Somatic mutation profile of tumor specimen TCGA-66-2782-01A (aliquot TCGA-66-2782-01A-01D-1522-08) from TCGA case TCGA-66-2782, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.8 years (26,237 days).
Specimen TCGA-66-2782-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba89ea8c-8999-4b45-be59-4e749696bcff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2782-11A (Solid Tissue Normal), aliquot TCGA-66-2782-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6b9b951-744e-463b-92d1-a32b3e729493

The open-access MAF lists 387 somatic variants for this specimen: 285 protein-altering or splice-affecting, 92 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 92, Nonsense Mutation 16, Frame Shift Del 12, Intron 5, RNA 5, Splice Site 4, Nonstop Mutation 2, Splice Region 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCX | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs587783563, CM078512, CM131056, COSV57567621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9445C>G p.P3149A | Missense Mutation (SNP) | VAF 80/416 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV101447176, COSV71285151; called by muse, mutect2, varscan2
- ABCA13 | c.9446C>A p.P3149Q | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV71285154; called by muse, mutect2, varscan2
- ABCA13 | c.12152G>T p.R4051M | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs746492849, COSV71285156; called by muse, mutect2, varscan2
- ABRAXAS2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1220847048, COSV53716479; called by muse, mutect2
- ACAN | c.203C>A p.P68Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs773473572, COSV61358362; called by muse, mutect2, varscan2
- ACAN | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61358371; called by muse, mutect2, varscan2
- ACSM4 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.214); catalogued as COSV68067361; called by muse, mutect2, varscan2
- ADAM23 | c.1585T>C p.C529R | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52211356; called by muse, mutect2, varscan2
- ADAMTS13 | c.1094G>T p.W365L | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV63020772; called by muse, mutect2, varscan2
- ADAMTS16 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777610990, COSV56978893; called by muse, mutect2, varscan2
- ADAMTS20 | c.5068G>A p.D1690N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.149); catalogued as rs1214878172, COSV101239554; called by muse, varscan2
- ADCYAP1R1 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as rs762991577, COSV58442582, COSV58444697; called by muse, mutect2, varscan2
- ADGRG4 | c.4793G>T p.R1598M | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV54952669; called by muse, mutect2, varscan2
- ADGRL4 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as COSV66060800; called by muse, mutect2, varscan2
- ADGRV1 | c.10310G>T p.W3437L | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV67982076; called by muse, mutect2, varscan2
- ALMS1 | c.5005G>T p.G1669W | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52506670; called by muse, mutect2, varscan2
- ANAPC1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs868008388, COSV61975180; called by muse, mutect2
- ANK2 | c.306C>G p.H102Q | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52153561; called by muse, mutect2, varscan2
- ANKS1B | c.3054G>T p.R1018S | Missense Mutation (SNP) | VAF 78/472 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV59116872; called by muse, mutect2, varscan2
- AOC1 | c.1813C>A p.L605M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV62867717; called by muse, mutect2, varscan2
- APCDD1L | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV64485895; called by muse, mutect2, varscan2
- ARPP21 | c.2253G>T p.Q751H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51792700, COSV51794789; called by muse, mutect2, varscan2
- ATG2B | c.5128A>T p.N1710Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55889854; called by muse, mutect2, varscan2
- C10orf71 | c.90C>G p.S30R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60506172; called by muse, varscan2
- CACNB2 | c.520C>T p.P174S (on ENST00000324631 / NM_201596.3; = p.P119S on NM_000724.4) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56617939; called by muse, mutect2
- CATSPERE | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247755957, COSV63677021; called by muse, mutect2, varscan2
- CCDC138 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV54565917; called by muse, mutect2
- CCDC158 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV101187388, COSV66355487; called by muse, mutect2, varscan2
- CDCP2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61283206; called by muse, mutect2, varscan2
- CDH9 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50263228; called by muse, mutect2, varscan2
- CDH9 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 64/350 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50263340, COSV50342466; called by muse, mutect2, varscan2
- CERT1 | c.1436C>T p.T479I (on ENST00000405807 / NM_001130105.1; = p.T351I on NM_005713.3) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs553535427, COSV54657039; called by muse, mutect2, varscan2
- CFH | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as CD127407, COSV62776957; called by muse, mutect2, varscan2
- CFHR4 | c.1214C>A p.A405D (on ENST00000367416 / NM_001201551.2; = p.A159D on NM_006684.5) | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as rs558763168, COSV52226766, COSV52227013; called by muse, mutect2, varscan2
- COL12A1 | c.5588G>T p.R1863L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.843); catalogued as rs377417661; called by muse, mutect2, varscan2
- COL1A2 | c.3118G>A p.D1040N | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs777241404, COSV51955592; called by muse, mutect2
- COL5A3 | c.5070C>A p.S1690R | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53408538; called by muse, mutect2, varscan2
- COL6A6 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567427258, COSV62021514; called by muse, mutect2, varscan2
- CTNNA2 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as COSV63556905; called by muse, mutect2, varscan2
- CTNND2 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV58876433; called by muse, mutect2, varscan2
- CUBN | c.5555G>C p.G1852A | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64712011; called by muse, mutect2, varscan2
- DACH1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.222); catalogued as COSV57494458; called by muse, mutect2
- DAGLA | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57195055; called by muse, mutect2, varscan2
- DDB1 | c.3393G>T p.K1131N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57101899; called by muse, mutect2, varscan2
- DDX60 | c.1998A>T p.L666F | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV67095811; called by muse, mutect2, varscan2
- DEPDC5 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.25); catalogued as COSV56694358, COSV56701951; called by muse, varscan2
- DNAH3 | c.3946G>C p.D1316H | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as rs749568373, COSV54512690, COSV54541192; called by muse, mutect2, varscan2
- DNAH7 | c.9535G>T p.A3179S | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.383); catalogued as COSV56757921; called by muse, mutect2, varscan2
- DOCK2 | c.1505T>A p.M502K | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56951029, COSV56971345; called by muse, mutect2, varscan2
- DPF3 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV63499514; called by muse, mutect2
- DPPA2 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV72117990; called by mutect2, varscan2
- DPPA3 | c.372G>A p.K124= | Splice Region (SNP) | VAF 32/171 reads (19%) | catalogued as COSV61502887; called by muse, mutect2, varscan2
- DSTYK | c.2485G>C p.V829L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65685977; called by muse, mutect2, varscan2
- DYDC2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55471932; called by muse, mutect2, varscan2
- EIF2AK3 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV57546192, COSV57548946; called by muse, mutect2
- EMILIN1 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs777716629, COSV53154022; called by muse, mutect2, varscan2
- EPB41L5 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 83/554 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs777262648, COSV55349776; called by muse, mutect2, varscan2
- EPM2A | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs1387516050, COSV62295792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPRS1 | c.1993A>T p.K665* | Nonsense Mutation (SNP) | VAF 52/229 reads (23%) | catalogued as COSV65098122; called by muse, mutect2, varscan2
- ERICH3 | c.2624C>A p.A875D | Missense Mutation (SNP) | VAF 132/461 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); catalogued as COSV100445201, COSV58603119; called by muse, mutect2, varscan2
- ESCO1 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 190/624 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV52519044; called by muse, varscan2
- ESRRG | c.57-1G>A p.X19_splice | Splice Site (SNP) | VAF 18/70 reads (26%) | catalogued as COSV63155630; called by muse, mutect2, varscan2
- FAM47B | c.1186C>A p.H396N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV61453113; called by muse, mutect2, varscan2
- FAM83B | c.2944A>G p.N982D | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV60920758; called by muse, mutect2
- FBN1 | c.2877C>G p.F959L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV57313035; called by muse, mutect2
- FBXO22 | c.1208A>G p.K403R | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV57617045; called by muse, mutect2, varscan2
- FGF14 | c.292A>T p.S98C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV65939400; called by muse, mutect2, varscan2
- FGFRL1 | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV53256975; called by muse, mutect2, varscan2
- FOXG1 | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV57396020; called by muse, mutect2, varscan2
- FRY | c.1344G>T p.R448S | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV66567578; called by muse, mutect2, varscan2
- FSIP2 | c.18079A>G p.T6027A | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV58088609; called by muse, mutect2, varscan2
- GADD45A | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV63974754; called by muse, mutect2, varscan2
- GALNT16 | c.730A>T p.S244C | Missense Mutation (SNP) | VAF 127/487 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61885294; called by muse, mutect2, varscan2
- GLI2 | c.4108C>G p.R1370G (on ENST00000361492 / NM_001374353.1; = p.R1387G on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV58038239, COSV58038591; called by muse, mutect2, varscan2
- GLP2R | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); catalogued as COSV52323408; called by muse, mutect2, varscan2
- GLUL | c.171G>T p.L57F | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59381922; called by muse, mutect2, varscan2
- GOLGA3 | c.2842G>T p.A948S | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as COSV52628219; called by muse, mutect2, varscan2
- GREB1 | c.4617T>A p.H1539Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52183841; called by muse, mutect2, varscan2
- GRID2 | c.2534C>G p.S845C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV56188997, COSV56198876; called by muse, mutect2
- GRIN2B | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV74204839, COSV74205379; called by muse, mutect2, varscan2
- GRXCR1 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as COSV67670965; called by muse, mutect2, varscan2
- HAT1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 131/467 reads (28%) | catalogued as COSV51362110; called by muse, mutect2, varscan2
- HECW2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as rs1475421465, COSV53654209; called by muse, mutect2, varscan2
- HEPHL1 | c.977T>A p.F326Y | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59890715; called by muse, mutect2
- HERC2 | c.2864A>G p.E955G | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55315852; called by muse, mutect2, varscan2
- HERC5 | c.1656C>A p.C552* | Nonsense Mutation (SNP) | VAF 37/164 reads (23%) | catalogued as COSV52038426; called by muse, mutect2, varscan2
- HERC5 | c.3074G>T p.*1025Lext*30 | Nonstop Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV52038438; called by muse, mutect2, varscan2
- HOXC10 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57726029; called by muse, mutect2, varscan2
- HOXC10 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57726036; called by muse, mutect2, varscan2
- HTR4 | c.952T>C p.S318P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV58792357; called by muse, mutect2
- IFIH1 | c.2114G>T p.R705I | Missense Mutation (SNP) | VAF 115/404 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55125600; called by muse, mutect2, varscan2
- IGLL1 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as COSV50769848; called by muse, mutect2, varscan2
- IL21R | c.1385G>C p.G462A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.173); catalogued as COSV61969413; called by muse, mutect2, varscan2
- INSR | c.2635G>T p.G879C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57160219; called by muse, mutect2, varscan2
- KCNA4 | c.213T>A p.C71* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV60251362; called by muse, mutect2, varscan2
- KCND3 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as rs1203819200, COSV56178022, COSV56188925; called by muse, mutect2, varscan2
- KIR2DL4 | c.386C>G p.A129G (on ENST00000396284; = p.A90G on NM_001080770.2) | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.257); catalogued as COSV100610636; called by muse, mutect2, varscan2
- KLF5 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV66613955; called by muse, mutect2, varscan2
- LDHB | c.840G>T p.G280= | Splice Region (SNP) | VAF 24/116 reads (21%) | catalogued as COSV63364499; called by muse, mutect2, varscan2
- LEFTY2 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV64746634; called by muse, mutect2, varscan2
- LILRB4 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV54404302; called by muse, mutect2, varscan2
- LPA | c.4495G>T p.V1499F | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.02); catalogued as COSV60299704; called by muse, mutect2, varscan2
- LRP1B | c.11645C>A p.A3882E | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV101253895, COSV67201436; called by muse, mutect2, varscan2
- LRP1B | c.6112G>A p.G2038R | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV67201440; called by muse, mutect2, varscan2
- LRP2 | c.9556C>A p.P3186T | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs781272785, COSV55547363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MACC1 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 103/436 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV60541663; called by muse, mutect2, varscan2
- MACF1 | c.11241G>C p.E3747D (on ENST00000372915; = p.E1680D on NM_012090.5) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV57114274; called by muse, mutect2, varscan2
- MACROD2 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.913); catalogued as COSV53964771; called by muse, mutect2, varscan2
- MAGEC1 | c.1660C>A p.Q554K | Missense Mutation (SNP) | VAF 223/483 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV53567279, COSV53570357; called by muse, mutect2, varscan2
- MAGEE1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV63909407; called by muse, mutect2, varscan2
- MBD2 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.124); catalogued as COSV56500589; called by muse, mutect2, varscan2
- MCCC1 | c.2119A>G p.R707G | Missense Mutation (SNP) | VAF 98/532 reads (18%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.933); catalogued as rs1165909921, COSV55607646; called by muse, mutect2, varscan2
- MCM10 | c.2554G>T p.G852C (on ENST00000484800 / NM_182751.3; = p.G851C on NM_018518.5) | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66333635; called by muse, mutect2, varscan2
- METTL24 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58821551; called by muse, mutect2, varscan2
- MSL3 | c.1193C>A p.S398* (on ENST00000312196 / NM_078629.4; = p.S232* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as rs1555907210, COSV56492354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSR1 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV50508882, COSV50520191; called by muse, mutect2, varscan2
- MTRES1 | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV60967792; called by muse, mutect2, varscan2
- MTUS2 | c.2348G>T p.S783I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70915444; called by muse, mutect2
- MUC16 | c.6935C>A p.T2312K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV67455945; called by muse, mutect2, varscan2
- MYH15 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as rs1159962758, COSV56307194; called by muse, varscan2
- MYH8 | c.4879G>T p.E1627* | Nonsense Mutation (SNP) | VAF 71/284 reads (25%) | catalogued as COSV67962467; called by muse, mutect2, varscan2
- MYO10 | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV72562997; called by muse, mutect2, varscan2
- MYOT | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51796202; called by muse, mutect2, varscan2
- MYOZ2 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 51/189 reads (27%) | catalogued as COSV61084435, COSV61086504; called by muse, mutect2, varscan2
- NAF1 | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV56803791; called by muse, mutect2, varscan2
- NAV1 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV55215766; called by muse, varscan2
- NAXE | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58039380; called by muse, mutect2, varscan2
- NCAM2 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV53065392; called by muse, mutect2, varscan2
- NCOA6 | c.4G>A p.V2I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); catalogued as COSV62862463; called by muse, mutect2, varscan2
- NEU2 | c.902C>G p.S301C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV52091986; called by muse, mutect2, varscan2
- NF1 | c.1007G>A p.W336* | Nonsense Mutation (SNP) | VAF 67/184 reads (36%) | catalogued as CM003946, CS001840, COSV62198259; called by muse, mutect2, varscan2
- NFIA | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64535603; called by muse, mutect2, varscan2
- NLRP13 | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV61620939; called by muse, mutect2, varscan2
- NR4A1 | c.1446G>A p.W482* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV54481188, COSV99671015; called by muse, mutect2, varscan2
- NRG3 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.17); catalogued as COSV64553157; called by muse, mutect2, varscan2
- NRSN1 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV65893801; called by muse, mutect2, varscan2
- NSD1 | c.6746A>T p.K2249I | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); catalogued as COSV100729431; called by muse, mutect2, varscan2
- NSG1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60372412; called by muse, mutect2, varscan2
- NSRP1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55933400; called by muse, mutect2, varscan2
- NUFIP1 | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV100997950, COSV64790831; called by muse, mutect2, varscan2
- OGFOD1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV55859675; called by muse, mutect2, varscan2
- OR11A1 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65820829; called by muse, mutect2, varscan2
- OR13C2 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV73377676; called by muse, mutect2, varscan2
- OR2AG2 | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV58454857; called by muse, mutect2, varscan2
- OR2G6 | c.217T>C p.F73L | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV58574061; called by muse, mutect2, varscan2
- OR2M2 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 138/671 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs778024720, COSV62898051; called by muse, mutect2, varscan2
- OR2T11 | c.745T>A p.Y249N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58185235; called by muse, mutect2, varscan2
- OR2T11 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV58185250; called by muse, mutect2, varscan2
- OR4A16 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 114/501 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV59042450; called by muse, mutect2, varscan2
- OR4C6 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV58603115; called by muse, mutect2, varscan2
- OR4M1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV60060307; called by muse, mutect2, varscan2
- OR52N2 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.297); catalogued as COSV57676448, COSV57677673; called by muse, mutect2, varscan2
- OR5D13 | c.736del p.H246Tfs*2 | Frame Shift Del (DEL) | VAF 43/231 reads (19%) | catalogued as COSV100686737; called by mutect2, pindel, varscan2
- OR5T2 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57588466; called by muse, mutect2, varscan2
- OR6N1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs748385243, COSV58647801; called by muse, mutect2, varscan2
- OR9I1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV56925702; called by muse, mutect2, varscan2
- OR9Q2 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61111650; called by muse, mutect2, varscan2
- OR9Q2 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 43/173 reads (25%) | catalogued as COSV61111657; called by muse, mutect2, varscan2
- OTOGL | c.1137G>T p.W379C (on ENST00000547103; = p.W370C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101509360; called by muse, mutect2
- PARD3B | c.2297G>A p.R766K (on ENST00000406610 / NM_001302769.2; = p.R704K on NM_152526.6) | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62506957; called by muse, mutect2, varscan2
- PBRM1 | c.1367T>C p.F456S | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56268862; called by muse, mutect2, varscan2
- PCDH11X | c.2644C>A p.L882M | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53454304; called by muse, mutect2, varscan2
- PCDHB12 | c.2104C>T p.L702F | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV53394751; called by muse, mutect2, varscan2
- PCDHGA3 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.219); catalogued as COSV53921556; called by muse, mutect2, varscan2
- PCDHGA3 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53921572; called by muse, mutect2, varscan2
- PEG3 | c.1498G>T p.V500F | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV55629494; called by muse, varscan2
- PEG3 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as COSV55629504; called by muse, varscan2
- PEX12 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV56777808; called by muse, mutect2, varscan2
- PF4 | c.300G>C p.E100D | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.549); catalogued as rs1312351422, COSV56020636; called by muse, varscan2
- PGA3 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100337370; called by mutect2, varscan2
- PGLYRP2 | c.1622C>A p.T541N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV52992496; called by mutect2, varscan2
- PHACTR4 | c.1031_1032insA p.L347Tfs*18 (on ENST00000373839 / NM_001350159.2; = p.L357Tfs*18 on NM_023923.4) | Frame Shift Ins (INS) | VAF 83/329 reads (25%) | catalogued as COSV100868467; called by mutect2, pindel, varscan2
- PHF8 | c.268G>T p.E90* (on ENST00000357988 / NM_001184896.1; = p.E54* on NM_015107.3) | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV57679369; called by muse, mutect2, varscan2
- PHLPP1 | c.4975G>T p.D1659Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53038298; called by muse, mutect2
- PI4KB | c.600C>A p.H200Q (on ENST00000368873 / NM_001369623.1; = p.H212Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV55016250; called by muse, mutect2, varscan2
- PIWIL1 | c.727A>T p.S243C | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV55345346; called by muse, mutect2, varscan2
- PKHD1L1 | c.644A>T p.H215L | Missense Mutation (SNP) | VAF 167/355 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.407); catalogued as COSV65740317; called by muse, mutect2, varscan2
- PLG | c.859G>C p.V287L | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51981873; called by muse, mutect2, varscan2
- PLIN1 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55583180; called by muse, mutect2, varscan2
- PLXNA1 | c.5140G>A p.A1714T | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV52524225; called by muse, mutect2, varscan2
- PM20D1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV65648695; called by muse, mutect2, varscan2
- PNLIPRP3 | c.671T>A p.I224N | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1261850743, COSV65047471; called by muse, mutect2, varscan2
- PPIP5K1 | c.3942C>G p.S1314R (on ENST00000396923; = p.S1289R on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV55807457; called by muse, mutect2, varscan2
- PPP1R16B | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV55374472; called by muse, mutect2, varscan2
- PPP1R3A | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV52879380; called by muse, mutect2, varscan2
- PRDM11 | c.1309C>G p.H437D (on ENST00000530656 / NM_001359633.1; = p.H403D on NM_001256695.1) | Missense Mutation (SNP) | VAF 70/455 reads (15%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.069); catalogued as rs1199524336, COSV55438794; called by muse, mutect2, varscan2
- PREX1 | c.3046T>A p.S1016T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as COSV64249961; called by muse, mutect2
- PREX2 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | catalogued as COSV55760462; called by muse, mutect2, varscan2
- PRKCB | c.1760G>C p.G587A | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as COSV57772748; called by muse, mutect2, varscan2
- PRKD2 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767210044, COSV52185467; called by muse, mutect2, varscan2
- PRMT8 | c.261+1G>A p.X87_splice | Splice Site (SNP) | VAF 57/296 reads (19%) | catalogued as COSV54212942; called by muse, mutect2, varscan2
- PROKR1 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 84/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547173684, COSV58137076; called by muse, mutect2, varscan2
- PROM2 | c.1697A>G p.Y566C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58297493; called by muse, mutect2, varscan2
- PRR23B | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs779024254, COSV61493072, COSV61493368; called by mutect2, varscan2
- PRSS16 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57915154; called by muse, mutect2, varscan2
- PTPRH | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs200030466, COSV54744055; called by muse, mutect2
- RAB32 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV62249015; called by muse, mutect2, varscan2
- RAI14 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs747432780, COSV54291732; called by muse, mutect2, varscan2
- RARS2 | c.505A>T p.N169Y | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65760576; called by muse, mutect2, varscan2
- RFPL4B | c.568C>G p.H190D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); catalogued as COSV71437198; called by muse, mutect2, varscan2
- RING1 | c.899C>G p.A300G | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63002425; called by muse, mutect2, varscan2
- RNF26 | c.322G>C p.A108P | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV60990110; called by muse, mutect2, varscan2
- ROBO4 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV60622732; called by muse, mutect2, varscan2
- RTN3 | c.1101G>A p.M367I (on ENST00000377819 / NM_001265589.2; = p.M348I on NM_201428.3) | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1317240768, COSV58027879; called by muse, mutect2
- RXFP3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs754698803, COSV57504049; called by muse, mutect2, varscan2
- SCML2 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52619854; called by muse, mutect2, varscan2
- SFMBT2 | c.2182G>T p.D728Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV62807422; called by muse, mutect2, varscan2
- SFMBT2 | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV62807433, COSV62812467; called by mutect2, varscan2
- SH3TC2 | c.1035G>C p.E345D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60462209; called by muse, mutect2, varscan2
- SIGLEC11 | c.1112A>G p.E371G | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1210268497, COSV101389546, COSV70221928; called by muse, mutect2
- SIGLEC8 | c.1319G>T p.G440V | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV58471729, COSV58472978; called by muse, mutect2, varscan2
- SLC22A4 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99569428; called by muse, mutect2, varscan2
- SLC25A35 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138474953; called by muse, mutect2, varscan2
- SLC2A7 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1190791083, COSV68901514; called by muse, mutect2, varscan2
- SLC4A1 | c.2345G>T p.R782L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs777827818, COSV52259238, COSV52262464; called by muse, mutect2, varscan2
- SLC5A1 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56684253; called by muse, mutect2, varscan2
- SLC5A6 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV60158886, COSV60160451; called by muse, mutect2, varscan2
- SLC8A1 | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60475584; called by muse, mutect2
- SLITRK5 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs770900467, COSV61521882; called by muse, mutect2, varscan2
- SPANXN3 | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV65140159; called by muse, mutect2, varscan2
- SPATA12 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.475); catalogued as COSV57589178, COSV57589302; called by muse, mutect2, varscan2
- SPATA31E1 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.087); catalogued as COSV57790523; called by muse, mutect2, varscan2
- SPEG | c.8995T>C p.Y2999H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56666018; called by muse, mutect2, varscan2
- SPTBN4 | c.5339G>T p.G1780V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151243; called by muse, mutect2, varscan2
- STAT4 | c.1301A>C p.Q434P | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV61828928; called by muse, mutect2, varscan2
- TAOK1 | c.133-2A>T p.X45_splice | Splice Site (SNP) | VAF 25/104 reads (24%) | catalogued as COSV55590050; called by muse, mutect2, varscan2
- TARS2 | c.1967G>C p.R656T | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV60872376; called by muse, mutect2, varscan2
- TEX55 | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55210044, COSV55210726; called by muse, mutect2, varscan2
- TGM6 | c.1170C>A p.F390L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52478646, COSV52478817; called by muse, mutect2, varscan2
- THAP10 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV51436347; called by muse, mutect2, varscan2
- THAP9 | c.2540G>C p.R847T | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV56356006; called by muse, mutect2
- TIMM17A | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV66170951; called by muse, mutect2, varscan2
- TMEM175 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV53278137, COSV53279688; called by muse, mutect2
- TMPRSS11D | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52222471; called by muse, mutect2, varscan2
- TNIK | c.3964C>G p.Q1322E | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52678061; called by muse, mutect2, varscan2
- TNIP3 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs763736712, COSV50246672, COSV50246841; called by muse, mutect2, varscan2
- TP53 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, mutect2, varscan2
- TRAT1 | c.559T>C p.*187Qext*8 | Nonstop Mutation (SNP) | VAF 74/312 reads (24%) | catalogued as rs1320484728, COSV55467916; called by muse, mutect2, varscan2
- TRHDE | c.1942G>C p.G648R | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV53838679, COSV53856522; called by muse, mutect2, varscan2
- TRHDE | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53838690; called by muse, mutect2, varscan2
- TRO | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV51499726; called by muse, mutect2, varscan2
- TTBK2 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV51158633; called by muse, mutect2, varscan2
- TTC17 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV50007251, COSV50007634; called by muse, mutect2, varscan2
- TYW1 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV62751920; called by muse, mutect2, varscan2
- UPF1 | c.2432G>A p.R811H (on ENST00000599848 / NM_001297549.2; = p.R800H on NM_002911.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53194910; called by muse, mutect2, varscan2
- UQCRB | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 172/387 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs199583530, COSV54629536; called by muse, mutect2, varscan2
- URB2 | c.3586G>C p.D1196H | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV50983715; called by muse, mutect2, varscan2
- USH2A | c.13095G>T p.W4365C | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV56349348; called by muse, mutect2, varscan2
- USH2A | c.13094G>T p.W4365L | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.062); catalogued as rs1163061829, CM150430, COSV56349366; called by muse, mutect2, varscan2
- USP33 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV62468816; called by muse, mutect2, varscan2
- USP40 | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); catalogued as COSV52478958, COSV52480289; called by muse, mutect2, varscan2
- USP6 | c.728C>G p.P243R | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV51478820; called by muse, mutect2, varscan2
- WDFY3 | c.7778G>C p.R2593T | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV55692174; called by muse, mutect2, varscan2
- WDR19 | c.3505C>G p.H1169D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV56463375; called by muse, mutect2, varscan2
- WDR72 | c.3204C>G p.D1068E | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV64743805; called by muse, mutect2, varscan2
- YBX3 | c.1004A>T p.Y335F | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54385019; called by muse, mutect2, varscan2
- Z83844.2 | c.205-2A>T p.X69_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV60927759; called by muse, mutect2, varscan2
- ZFPM2 | c.2498G>T p.S833I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65872589, COSV65873013; called by muse, mutect2
- ZIM2 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1368006859, COSV55629485; called by muse, mutect2, varscan2
- ZMYM6 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as rs1234171743, COSV58183978; called by muse, mutect2, varscan2
- ZNF117 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs746899502, COSV51426785; called by muse, mutect2, varscan2
- ZNF165 | c.1035G>T p.Q345H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV66102195; called by muse, mutect2, varscan2
- ZNF214 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53481218; called by muse, mutect2, varscan2
- ZNF493 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100828552, COSV62749591; called by muse, mutect2, varscan2
- ZNF585A | c.599C>A p.S200Y (on ENST00000292841 / NM_001288800.2; = p.S145Y on NM_152655.3) | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.348); catalogued as COSV53062470; called by muse, mutect2
- ZNF592 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55435765; called by muse, mutect2, varscan2
- ZNF592 | c.1688A>C p.N563T | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55435774; called by muse, varscan2
- ZNF750 | c.1327G>T p.G443* | Nonsense Mutation (SNP) | VAF 105/241 reads (44%) | catalogued as COSV53959396; called by muse, mutect2, varscan2
- ZNF804B | c.482G>T p.C161F | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.686); catalogued as COSV60822249; called by muse, mutect2, varscan2
- ZNF99 | c.1944del p.Y649Tfs*21 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | catalogued as COSV101233840; called by mutect2, pindel, varscan2
- ZP4 | c.297G>C p.W99C | Missense Mutation (SNP) | VAF 68/319 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV63911541; called by muse, mutect2, varscan2
- ZSCAN31 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); catalogued as COSV100716976, COSV60180310, COSV60180547; called by muse, mutect2, varscan2
- ZSCAN31 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV60180554; called by muse, mutect2, varscan2
- ARHGAP36 | c.1239_1245del p.V415Pfs*2 | Frame Shift Del (DEL) | VAF 104/294 reads (35%) | called by mutect2, pindel, varscan2
- BSN | c.11763del p.K3921Nfs*14 | Frame Shift Del (DEL) | VAF 91/311 reads (29%) | called by mutect2, pindel, varscan2
- CEP162 | c.1291del p.T431Lfs*3 | Frame Shift Del (DEL) | VAF 39/305 reads (13%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1094_1095del p.R365Lfs*68 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- LPIN1 | c.418_431del p.I140Dfs*27 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel*
- OR2T5 | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- RASA1 | c.2281del p.L761Ffs*13 | Frame Shift Del (DEL) | VAF 54/166 reads (33%) | called by mutect2, varscan2
- SECTM1 | c.17_24del p.L6Pfs*23 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- SMC3 | c.2041del p.D681Mfs*9 | Frame Shift Del (DEL) | VAF 35/179 reads (20%) | called by mutect2, pindel, varscan2
- UNC93A | c.988del p.H330Tfs*5 | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | called by mutect2, pindel, varscan2
- ZNF513 | c.1245del p.Y416Tfs*42 | Frame Shift Del (DEL) | VAF 85/421 reads (20%) | called by mutect2, pindel, varscan2
- ACCS | c.1002G>C p.T334= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV55457173, COSV55457619; called by muse, mutect2, varscan2
- ALLC | c.213C>A p.V71= | Silent (SNP) | VAF 44/214 reads (21%) | catalogued as COSV52993714; called by muse, mutect2, varscan2
- ANKH | c.21C>G p.L7= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52478974; called by muse, mutect2, varscan2
- ATP6V1A | c.1698A>G p.T566= | Silent (SNP) | VAF 53/191 reads (28%) | catalogued as rs764469987, COSV56361583; called by muse, mutect2, varscan2
- BCL11A | c.273G>A p.E91= | Silent (SNP) | VAF 19/228 reads (8%) | catalogued as COSV59627085; called by muse, mutect2
- C6 | c.1548C>T p.A516= | Silent (SNP) | VAF 56/211 reads (27%) | catalogued as rs1054262851, COSV54707909; called by muse, mutect2, varscan2
- CCDC158 | c.423G>A p.E141= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs745891494, COSV66355488; called by muse, mutect2, varscan2
- CCDC62 | c.933G>A p.Q311= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV53431851; called by muse, mutect2, varscan2
- CCNDBP1 | c.904C>T p.L302= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as COSV55746679; called by muse, mutect2, varscan2
- CDCP2 | c.279G>T p.G93= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV61283201, COSV61283226; called by muse, mutect2, varscan2
- CDHR3 | c.1623C>T p.A541= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV58415393; called by muse, mutect2, varscan2
- CEP350 | c.3897G>A p.L1299= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV62600361; called by muse, mutect2, varscan2
- CLDN12 | c.525G>T p.V175= | Silent (SNP) | VAF 133/543 reads (24%) | catalogued as COSV55306562; called by muse, mutect2, varscan2
- CLEC12A | c.480C>A p.A160= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as COSV58560938; called by muse, mutect2, varscan2
- CLVS1 | c.438C>G p.A146= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV100370494, COSV57972863; called by muse, mutect2
- CNTNAP2 | c.3303C>T p.D1101= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as rs772181075, COSV62161835; called by muse, mutect2, varscan2
- COPG2 | c.720A>G p.L240= | Silent (SNP) | VAF 73/255 reads (29%) | catalogued as COSV58404558; called by muse, mutect2, varscan2
- CTAGE6 | c.931C>T p.L311= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV101417859; called by mutect2, varscan2
- CYP2C18 | c.420C>T p.S140= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV53671026; called by muse, mutect2, varscan2
- DAP3 | c.960G>A p.R320= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs767880162, COSV58019942; called by muse, mutect2, varscan2
- DLG2 | c.1200C>A p.T400= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV54632809, COSV54638887; called by muse, mutect2, varscan2
- DRAM2 | c.465C>G p.V155= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV54415024; called by muse, mutect2, varscan2
- EDRF1 | c.1299G>A p.K433= (on ENST00000356792 / NM_001202438.2; = p.K399= on NM_015608.2) | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV61763038; called by muse, mutect2, varscan2
- EFNB2 | c.63A>G p.R21= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV55364087; called by muse, mutect2, varscan2
- EMC9 | c.18C>T p.I6= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV52823698; called by muse, varscan2
- ENPP3 | c.372T>C p.D124= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as rs765294171, COSV62953655; called by muse, mutect2, varscan2
- EVX1 | c.108G>T p.P36= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV56084988; called by muse, mutect2, varscan2
- FAT4 | c.3033G>T p.V1011= | Silent (SNP) | VAF 72/330 reads (22%) | catalogued as COSV67883422; called by muse, mutect2, varscan2
- FER | c.807A>T p.T269= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV55287172; called by muse, mutect2, varscan2
- FMO1 | c.1140T>A p.P380= | Silent (SNP) | VAF 45/174 reads (26%) | catalogued as COSV61445171; called by muse, mutect2, varscan2
- GAD2 | c.1041C>G p.L347= | Silent (SNP) | VAF 35/378 reads (9%) | catalogued as rs1054225395, COSV52154202; called by muse, mutect2
- GLCCI1 | c.1398A>T p.L466= | Silent (SNP) | VAF 150/684 reads (22%) | catalogued as rs376472624; called by muse, mutect2, varscan2
- GP2 | c.862C>T p.L288= (on ENST00000381362 / NM_001007240.3; = p.L285= on NM_001502.4) | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as COSV56892836; called by muse, mutect2, varscan2
- GPR153 | c.135G>C p.L45= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV64938325; called by muse, mutect2, varscan2
- GRIA2 | c.2622C>T p.N874= | Silent (SNP) | VAF 67/349 reads (19%) | catalogued as rs747357354, COSV52386476, COSV99644602; called by muse, mutect2, varscan2
- GRM1 | c.3162C>A p.G1054= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV51122389; called by muse, mutect2
- GRM4 | c.1377A>T p.A459= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as COSV65212005; called by muse, mutect2, varscan2
- HEPHL1 | c.3354C>A p.I1118= | Silent (SNP) | VAF 22/216 reads (10%) | catalogued as COSV59890723; called by muse, mutect2, varscan2
- HERC2 | c.2865G>A p.E955= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV55315827; called by muse, mutect2, varscan2
- HIVEP1 | c.4389A>G p.P1463= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as rs770844511, COSV65100101; called by muse, mutect2, varscan2
- HTR1A | c.1179T>A p.S393= | Silent (SNP) | VAF 44/500 reads (9%) | catalogued as COSV60500329; called by muse, mutect2
- ITPRID1 | c.1983A>G p.E661= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV60072211; called by muse, mutect2, varscan2
- KIF2B | c.1191G>T p.V397= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV52128847; called by muse, mutect2, varscan2
- KLHL38 | c.1509A>G p.K503= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as COSV58086692; called by muse, mutect2, varscan2
- KRT1 | c.1446C>T p.Y482= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52865849; called by muse, mutect2, varscan2
- LRP1B | c.2178G>A p.G726= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs777710899, COSV67201444; called by muse, mutect2, varscan2
- LRRK2 | c.7431G>T p.R2477= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV54148638; called by muse, mutect2, varscan2
- MAGI2 | c.594T>C p.N198= | Silent (SNP) | VAF 135/538 reads (25%) | catalogued as COSV62643492; called by muse, mutect2, varscan2
- MED13L | c.3231C>T p.T1077= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs201077645, COSV56117831; called by muse, mutect2
- MYBPC1 | c.2685C>A p.I895= (on ENST00000550270 / NM_206820.2; = p.I902= on NM_002465.4) | Silent (SNP) | VAF 100/379 reads (26%) | catalogued as COSV62252041; called by muse, mutect2, varscan2
- MYH6 | c.2070G>T p.L690= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV62449045; called by muse, mutect2, varscan2
- NAV3 | c.3858C>A p.G1286= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV57071037; called by muse, mutect2, varscan2
- NCOA6 | c.5298G>A p.L1766= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV62862458; called by muse, mutect2, varscan2
- NLRP13 | c.1176G>T p.R392= | Silent (SNP) | VAF 62/268 reads (23%) | catalogued as rs919797325, COSV61620943; called by muse, mutect2, varscan2
- NPSR1 | c.426C>T p.L142= | Silent (SNP) | VAF 34/320 reads (11%) | catalogued as COSV62198714; called by muse, mutect2, varscan2
- NRSN1 | c.222C>A p.I74= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as COSV65893799; called by muse, mutect2, varscan2
- OR14I1 | c.606A>G p.S202= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV61199314; called by muse, mutect2, varscan2
- OR2A12 | c.222G>A p.S74= | Silent (SNP) | VAF 84/265 reads (32%) | catalogued as rs1052571969, COSV68821200; called by muse, mutect2, varscan2
- OR4K17 | c.621C>T p.S207= | Silent (SNP) | VAF 100/446 reads (22%) | catalogued as rs1229323000, COSV59647682; called by muse, mutect2, varscan2
- OR8I2 | c.669C>A p.A223= | Silent (SNP) | VAF 65/272 reads (24%) | catalogued as rs200261114, COSV56167179; called by muse, mutect2, varscan2
- OR9I1 | c.903C>T p.F301= | Silent (SNP) | VAF 48/433 reads (11%) | catalogued as COSV56925689, COSV56925783; called by muse, mutect2, varscan2
- PCDH10 | c.915G>T p.P305= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV52090642, COSV52096256; called by muse, mutect2, varscan2
- PCDH10 | c.2871T>C p.S957= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as rs937490253, COSV52090649; called by muse, mutect2, varscan2
- PCDHB15 | c.1809G>A p.S603= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs782813959; called by muse, mutect2
- PCNT | c.2085A>T p.L695= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as COSV64026725; called by muse, mutect2, varscan2
- PDZD8 | c.2715T>A p.L905= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs1413969556, COSV53689423; called by muse, mutect2, varscan2
- PHF13 | c.492C>T p.P164= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV50010784; called by muse, mutect2, varscan2
- PIK3CG | c.1383C>G p.L461= | Silent (SNP) | VAF 52/199 reads (26%) | catalogued as COSV63247154; called by muse, mutect2, varscan2
- PMPCA | c.768G>A p.V256= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV65509058; called by muse, mutect2, varscan2
- REG1A | c.330C>A p.R110= | Silent (SNP) | VAF 58/275 reads (21%) | catalogued as COSV52069221; called by muse, mutect2, varscan2
- RHBDF1 | c.1110G>T p.P370= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1316759077, COSV51953929, COSV51954391; called by muse, mutect2, varscan2
- RHO | c.291C>A p.T97= | Silent (SNP) | VAF 52/255 reads (20%) | catalogued as COSV56212906; called by muse, mutect2, varscan2
- ROBO4 | c.2223C>A p.P741= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV60622719; called by muse, mutect2, varscan2
- SDSL | c.333C>T p.A111= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs758385489, COSV61884419, COSV61885283; called by muse, mutect2, varscan2
- SEC14L1 | c.2091G>C p.L697= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV66721502; called by muse, mutect2, varscan2
- SF3B4 | c.234A>G p.K78= | Silent (SNP) | VAF 35/152 reads (23%) | catalogued as COSV54964795; called by muse, mutect2, varscan2
- SIPA1L3 | c.4914G>A p.L1638= | Silent (SNP) | VAF 42/279 reads (15%) | catalogued as rs1287658282, COSV55911427; called by muse, mutect2, varscan2
- SLC1A2 | c.990C>T p.I330= | Silent (SNP) | VAF 25/179 reads (14%) | catalogued as rs780093453, COSV53519898; called by muse, mutect2, varscan2
- SLC30A5 | c.1905C>A p.L635= | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as COSV67449027; called by muse, mutect2, varscan2
- ST8SIA3 | c.642C>T p.I214= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV60653711; called by muse, mutect2, varscan2
- STS | c.990C>T p.T330= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV54267141; called by muse, mutect2, varscan2
- TAF3 | c.177A>T p.T59= | Silent (SNP) | VAF 64/313 reads (20%) | catalogued as COSV60204824; called by muse, mutect2, varscan2
- TENT2 | c.1056C>G p.L352= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as rs749512048, COSV57136218; called by muse, mutect2, varscan2
- THAP10 | c.273G>T p.R91= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51436355; called by muse, mutect2, varscan2
- TTLL6 | c.1152C>G p.L384= (on ENST00000393382 / NM_001130918.3; = p.L77= on NM_173623.3) | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as COSV64976692; called by muse, mutect2, varscan2
- USP8 | c.168G>A p.E56= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs925954472, COSV56163410; called by muse, mutect2, varscan2
- VPS13B | c.10884G>A p.A3628= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs768029540, COSV62137624; ClinVar: likely benign; called by muse, mutect2
- VSTM1 | c.18C>G p.L6= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as COSV58074363; called by muse, mutect2
- WDR88 | c.312T>A p.A104= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV63451008; called by muse, mutect2, varscan2
- XIRP2 | c.2286T>C p.L762= (on ENST00000628543; = p.L937= on NM_152381.6) | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV54691031; called by muse, mutect2, varscan2
- ZFHX4 | c.6693G>A p.T2231= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs757512171, COSV50651044; called by muse, mutect2, varscan2
- ZNF770 | c.1785C>T p.P595= | Silent (SNP) | VAF 49/350 reads (14%) | catalogued as rs765584279, COSV62544007; called by muse, mutect2, varscan2
- C14orf177 | n.685C>T | RNA (SNP) | VAF 34/172 reads (20%) | catalogued as rs1002926043, COSV57900647; called by muse, mutect2, varscan2
- CFAP74 | c.4654-259T>C | Intron (SNP) | VAF 9/88 reads (10%) | catalogued as COSV60586474; called by muse, mutect2
- DPP6 | c.627+21074A>T | Intron (SNP) | VAF 83/252 reads (33%) | catalogued as COSV100126175; called by muse, varscan2
- DTNA | c.1662+2100C>G | Intron (SNP) | VAF 14/121 reads (12%) | catalogued as rs773615687, COSV99313385; called by muse, mutect2, varscan2
- KIF1B | c.2115+6647G>A | Intron (SNP) | VAF 14/109 reads (13%) | catalogued as rs754969112, COSV99823596; called by muse, mutect2, varscan2
- OFCC1 | n.435G>A | RNA (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- PKD1L2 | n.722C>A | RNA (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- SNORD115-21 | n.60C>T | RNA (SNP) | VAF 42/368 reads (11%) | catalogued as rs186634247; called by muse, varscan2
- SNORD115-32 | n.17C>A | RNA (SNP) | VAF 75/337 reads (22%) | catalogued as rs892785715; called by muse, mutect2, varscan2
- SYNPO2L | c.773-2112C>A | Intron (SNP) | VAF 25/119 reads (21%) | catalogued as rs1207467851, COSV100866392; called by muse, mutect2, varscan2
